Surgical pathology report (de-identified scan), TCGA case TCGA-E3-A3E1, project TCGA-THCA (Thyroid Carcinoma), tissue source site Roswell Park, specimen TCGA-E3-A3E1-01A (Primary Tumor).

Surgery Date

SPECIMENS:

A. RIGHT THYROID LOBE

DIAGNOSIS:

- A. THYROID, RIGHT, LOBECTOMY:
- PAPILLARY THYROID CARCINOMA, USUAL VARIANT (see Synoptic Report).
- MARGINS ARE NEGATIVE FOR CARCINOMA.
- TWO LYMPH NODES WITH NO EVIDENCE OF CARCINOMA (0/2).

THYROID CANCER SYNOPTIC REPORT

Specimen Type: Lobectomy, right lobe
Tumor Site: Right lobe
Tumor Focality: Unifocal
Tumor Size (Largest nodule): Greatest dimension: 1.5 cm.
Additional dimensions: 1.5 x 1.0 cm.
Histologic Type: Papillary carcinoma
Margins: Margins uninvolved by carcinoma
Venous/Lymphatic Invasion: Absent
Additional Findings: Nodular goiter, chronic inflammation
Lymph Nodes: 0/2; negative for carcinoma
Pathologic Stage: pT1 N0 MX (2 lymph nodes)

SPECIMEN(S):

A. RIGHT THYROID LOBE

CLINICAL HISTORY:

Not given

GROSS DESCRIPTION:

A. RIGHT THYROID LOBE

Received fresh labeled with the patient's name, , and designated as "right thyroid lobe" is an unoriented 16 gram partial lobectomy specimen measuring 4.0 x 3.1 x 2.2 cm. The external surface is red-brown and lobulated. The entire external surface is inked black and sectioned to reveal a 1.5 x 1.5 x 1.0 cm white-tan, soft, well circumscribed mass located at the mid section of the specimen. Tissue is procured from the tumor for the tissue bank. The tumor is multicystic with the cystic spaces measuring approximately 0.1 cm in maximal diameter. No area of hemorrhage or calcification is noted. The attached specimen is submitted serially in cassettes A1-10.

Gross Dictation: ,

Microscopic/Diagnostic Dictation: , M.D., Pathologist

Microscopic/Diagnostic Dictation: , M.D., Pathologist

Final Review: , M.D., Pathologist

Final: , M.D., Pathologist

1CD-0-3

carcinoma, papillary, thyroid 8260/3
Site: Thyroid, NOS C73.9 lw
10/26/11

stPAA Discrepancy		/

lw 10/26/11

Source: NCI Genomic Data Commons file f5005c19-1f8f-4eae-ba4c-a2862b1fdc70 (TCGA-E3-A3E1.EA6E1AAE-435A-4092-B4F3-59FC83D78BC4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).